Somatic mutation profile of tumor specimen 0DRCJZ from CCDI case PBCFTL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (80 days).
Specimen 0DRCJZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 107d976e-7d6b-4bd3-8fc7-e5b7f7334a80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRCJX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aabaad5e-b1f8-4759-a6e3-3036266c4637

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2131A>T p.K711* | Nonsense Mutation (SNP) | VAF 463/517 reads (90%) | called by muse, varscan2
- TCIRG1 | c.870G>A p.P290= | Silent (SNP) | VAF 118/355 reads (33%) | catalogued as rs775370689; called by muse, varscan2
- TRAF4 | c.*28C>T | 3'UTR (SNP) | VAF 105/192 reads (55%) | catalogued as rs781437530; called by muse, varscan2
